Somatic mutation profile of tumor specimen TCGA-MP-A4TH-01A (aliquot TCGA-MP-A4TH-01A-31D-A25L-08) from TCGA case TCGA-MP-A4TH, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.5 years (25,759 days).
Specimen TCGA-MP-A4TH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5098297b-dbff-4450-b7e1-c4467e65b3ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TH-10A (Blood Derived Normal), aliquot TCGA-MP-A4TH-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd5571bd-0192-4e4b-af24-f1dcd1d80f74

The open-access MAF lists 119 somatic variants for this specimen: 96 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 20, Nonsense Mutation 8, Frame Shift Del 4, Splice Site 4, Intron 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.11648T>A p.L3883Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263343; called by muse, mutect2, varscan2
- ATG4A | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV100619535, COSV58966519; called by muse, mutect2, varscan2
- ATP7A | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100430198; called by muse, mutect2, varscan2
- B2M | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1435502075, COSV100837543, COSV104421991; called by muse, mutect2, varscan2
- BHLHE41 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs561601016, COSV99658187; called by muse, mutect2, varscan2
- BRCA2 | c.2498T>G p.L833R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV101203863; called by muse, mutect2, varscan2
- CCDC71 | c.1237A>C p.K413Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100422269; called by muse, mutect2
- CENPI | c.1826+1G>C p.X609_splice | Splice Site (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99514979; called by muse, mutect2, varscan2
- CFAP100 | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.959); catalogued as COSV100729054; called by muse, mutect2
- CLMN | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100111976; called by muse, mutect2
- CMTR2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV100578959; called by muse, mutect2, varscan2
- COL12A1 | c.6355C>T p.P2119S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs759184604, COSV100485316; called by muse, mutect2, varscan2
- DDX59 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV100494342; called by muse, mutect2
- DDX59 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 22/228 reads (10%) | catalogued as COSV100494356; called by muse, mutect2
- DNAH1 | c.1073G>C p.R358P | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101324567; called by muse, mutect2
- EIF2AK3 | c.3072G>T p.Q1024H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100303364; called by muse, mutect2
- FAM47A | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 33/130 reads (25%) | catalogued as COSV100649692; called by muse, mutect2, varscan2
- FAM83B | c.2639G>T p.R880M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV100173974, COSV60922627, COSV60926479; called by muse, mutect2, varscan2
- FAM83B | c.2640G>T p.R880S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100173977; called by muse, mutect2, varscan2
- FAT3 | c.11012G>A p.R3671H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs535363004, COSV53106675, COSV99035396; called by muse, mutect2
- FGF23 | c.732C>G p.C244W | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV99426206; called by muse, mutect2, varscan2
- FMN2 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV60415000; called by muse, mutect2, varscan2
- GAPVD1 | c.3919G>T p.E1307* (on ENST00000394104; = p.E1316* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99782589; called by muse, mutect2, varscan2
- GOLGA4 | c.6617A>G p.D2206G | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV100728628; called by muse, mutect2, varscan2
- GP5 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV99756114; called by muse, mutect2, varscan2
- GRIN1 | c.1339+2T>A p.X447_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100159758; called by muse, mutect2, varscan2
- HLX | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV65044824; called by muse, mutect2, varscan2
- HUWE1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99470490; called by muse, mutect2, varscan2
- IDO1 | c.149T>A p.I50K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99503137; called by muse, mutect2, varscan2
- IGF2BP1 | c.52T>A p.L18M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99288209; called by muse, mutect2, varscan2
- KDM3B | c.3338C>A p.A1113D | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV100069122; called by muse, mutect2
- LENG8 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs770183845, COSV100457079; called by muse, mutect2, varscan2
- LRIF1 | c.1140C>G p.D380E | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as COSV100870788; called by muse, mutect2, varscan2
- LRP1B | c.11275G>T p.A3759S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101251686; called by muse, mutect2, varscan2
- MBNL3 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100898425; called by muse, mutect2, varscan2
- MED16 | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515080; called by muse, mutect2
- MSTN | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640487; called by muse, mutect2, varscan2
- MYOT | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99524713; called by muse, mutect2, varscan2
- NBPF3 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100558352; called by muse, mutect2, varscan2
- NHS | c.2555C>A p.P852Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101196368; called by mutect2, varscan2
- NKAP | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV101004161; called by muse, mutect2, varscan2
- NLRP11 | c.271+1G>A p.X91_splice | Splice Site (SNP) | VAF 43/121 reads (36%) | catalogued as rs372781070; called by muse, mutect2, varscan2
- NOX5 | c.2036C>A p.A679E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99533203; called by muse, mutect2, varscan2
- NRK | c.4069G>T p.D1357Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99686420, COSV99686487; called by muse, mutect2, varscan2
- OPRK1 | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99653663; called by muse, mutect2, varscan2
- OR9G1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100380215; called by muse, mutect2
- PCDHGB6 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99529687; called by muse, mutect2, varscan2
- PDZRN3 | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99727112; called by muse, mutect2, varscan2
- PFKFB1 | c.684G>C p.M228I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | PolyPhen benign (0); catalogued as COSV100895589, COSV66629632; called by muse, mutect2, varscan2
- PKN1 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV99660797; called by muse, mutect2, varscan2
- PLXNB2 | c.3737G>A p.R1246Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833832; called by muse, mutect2, varscan2
- PTCHD4 | c.1405A>T p.I469F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100259918; called by muse, mutect2
- PTPN14 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100872308; called by muse, mutect2
- PTPRH | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs148819962, COSV99670639; called by muse, mutect2, varscan2
- RAB11FIP1 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV99769641; called by muse, mutect2, varscan2
- RAG1 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.017); catalogued as COSV100200628; called by muse, mutect2, varscan2
- RCAN2 | c.562C>A p.R188S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100149047, COSV57819878; called by muse, mutect2, varscan2
- RELN | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV100632222; called by muse, mutect2, varscan2
- REPIN1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101262581; called by muse, mutect2, varscan2
- RTN2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV55592503; called by muse, mutect2, varscan2
- SEMA6D | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.038); catalogued as COSV100316366; called by muse, mutect2, varscan2
- SFXN4 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV100340918; called by muse, mutect2, varscan2
- SKAP1 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100411299; called by muse, mutect2, varscan2
- SKIDA1 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV101481246; called by muse, mutect2
- TARBP1 | c.3883A>T p.K1295* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as COSV99241016; called by muse, mutect2, varscan2
- TDRD6 | c.2321T>C p.V774A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100287056; called by muse, mutect2, varscan2
- TFE3 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100252284, COSV100252580; called by muse, mutect2, varscan2
- TGM7 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV101476814; called by muse, mutect2, varscan2
- TLR1 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368957715; called by muse, mutect2, varscan2
- TNFAIP3 | c.615G>T p.R205S | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52798773; called by muse, mutect2, varscan2
- TRAIP | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as COSV100512990; called by muse, mutect2, varscan2
- TRIO | c.4102G>T p.D1368Y | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100709753; called by muse, mutect2, varscan2
- TRPS1 | c.1243G>T p.V415L (on ENST00000220888 / NM_001330599.2; = p.V428L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV99628121; called by muse, mutect2, varscan2
- TTN | c.58509G>T p.R19503S (on ENST00000591111; = p.R12079S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | PolyPhen possibly damaging (0.83); catalogued as COSV100592534; called by muse, mutect2, varscan2
- TTN | c.27880T>A p.C9294S (on ENST00000591111; = p.C8367S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | PolyPhen benign (0.273); catalogued as COSV100592537; called by muse, mutect2, varscan2
- USH2A | c.11960A>G p.K3987R | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100228406; called by muse, mutect2, varscan2
- USP9X | c.4366G>A p.A1456T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100198407; called by muse, mutect2, varscan2
- XIRP2 | c.4588C>A p.R1530S (on ENST00000628543; = p.R1705S on NM_152381.6) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV54680451; called by muse, mutect2, varscan2
- XKR4 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV59299789; called by muse, mutect2, varscan2
- XRN1 | c.309-2A>T p.X103_splice | Splice Site (SNP) | VAF 14/101 reads (14%) | catalogued as COSV99377139; called by muse, mutect2, varscan2
- ZNF180 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV99659573; called by muse, mutect2, varscan2
- ZNF282 | c.1790C>T p.T597M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100021376; called by mutect2, varscan2
- ZNF345 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100080134; called by muse, mutect2, varscan2
- ZNF532 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV100265919; called by muse, mutect2, varscan2
- ZNF567 | c.1078A>T p.T360S (on ENST00000536254 / NM_001322913.1; = p.T329S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as COSV100658620; called by muse, mutect2, varscan2
- ZNF782 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100001107; called by muse, mutect2, varscan2
- ZNF804B | c.1169T>A p.L390Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100301578; called by muse, mutect2, varscan2
- BRD7 | c.1825T>A p.Y609N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.255); called by muse, mutect2
- IGHV1OR21-1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- IGKV1-27 | c.298del p.L100Cfs*? | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | called by mutect2, pindel, varscan2
- LRATD1 | c.124del p.E42Kfs*14 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- MTNR1A | c.754del p.A252Lfs*3 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PIK3C3 | c.820dup p.A274Gfs*10 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by pindel, varscan2
- PTPN13 | c.6436G>C p.D2146H (on ENST00000411767 / NM_080683.3; = p.D2127H on NM_006264.3) | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2
- STEAP1 | c.8_14del p.S3Kfs*12 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- AGFG1 | c.285A>T p.G95= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100028311; called by muse, mutect2, varscan2
- C12orf40 | c.654A>G p.T218= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1249094881, COSV100209600; called by muse, mutect2, varscan2
- CCDC71 | c.672G>T p.R224= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs1157073889, COSV100422271; called by muse, mutect2, varscan2
- CENPL | c.132A>T p.P44= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV100616237; called by muse, mutect2, varscan2
- CHMP1B | c.582C>T p.R194= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99302999; called by muse, varscan2
- DIP2B | c.2376C>T p.I792= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99997820; called by muse, mutect2, varscan2
- ETFDH | c.1401G>C p.G467= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100306697; called by muse, mutect2, varscan2
- KCNG4 | c.1293C>T p.G431= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100376879; called by muse, mutect2, varscan2
- KIF6 | c.2163A>G p.Q721= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs960435080, COSV99757015; called by muse, mutect2, varscan2
- LHX4 | c.813T>C p.N271= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as rs777542565, COSV99761132; called by muse, mutect2, varscan2
- LRRIQ1 | c.1893A>G p.Q631= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101279403; called by muse, mutect2
- MRPS18B | c.216C>T p.P72= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs188820794; called by muse, mutect2, varscan2
- MYOM2 | c.972A>G p.K324= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100036531; called by muse, mutect2, varscan2
- NTNG2 | c.1332G>A p.T444= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1273065468, COSV62367854; called by muse, mutect2, varscan2
- PLEKHH1 | c.3576G>T p.L1192= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100232589; called by muse, mutect2, varscan2
- SLC4A11 | c.1530G>T p.T510= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV101195875; called by muse, mutect2, varscan2
- UBAP2 | c.423C>G p.G141= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as COSV100670873, COSV62546477; called by muse, mutect2, varscan2
- ZNF160 | c.2205T>C p.C735= | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as COSV100762215; called by mutect2, varscan2
- ZNF202 | c.864C>T p.S288= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100278897; called by muse, mutect2, varscan2
- ZXDB | c.2145A>G p.K715= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100885764; called by muse, mutect2, varscan2
- SPEG | c.389-1530del | Intron (DEL) | VAF 29/178 reads (16%) | called by mutect2, pindel, varscan2
- TUBB7P | n.1154C>A | RNA (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- VEGFA | chr6:43771195 G>T | 5'Flank (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
